Surgical pathology report (de-identified scan), TCGA case TCGA-EE-A29E, project TCGA-SKCM (Skin Cutaneous Melanoma), tissue source site University of Sydney, specimen TCGA-EE-A29E-06A (Metastatic).

DOB/Age/Sex:
Location:
Requested by:
Requested on:
Specimen Rcvd:
Accession No.:
Copies to:

HISTOPATHOLOGY REPORT

CLINICAL DETAILS

Left radial axillary dissection for melanoma. Left axillary FNA - melanoma.
Refer to:

MACROSCOPIC DESCRIPTION

(Dr

LEFT AXILLARY CONTENTS: An aggregate of fibrofatty tissue, with one end attached to a portion of skeletal muscle. The specimen measures 140x80x35mm. The specimen is dissected from the opposite end towards the muscle end and embedded in this order. The cut surface shows multiple enlarged lymph nodes with the largest measuring 30mm with a black cut surface. The skeletal muscle is unremarkable. A portion from the largest node was taken for tumour banking in the fresh state.

- A. Three nodes.
- B. Four nodes.
- C. Four nodes.
- D. Three nodes.
- E. Two nodes.
- F. Two nodes.
- G. Four nodes.
- H. ?Four nodes.
- I. Four nodes.
- K&N. The largest node divided.

1 CD-0-3

Melanoma, NOS 8720/3

Site: lymph node, Axilla c77.3

hw
6/2/11

All lymph nodes are embedded.

MICROSCOPIC REPORT

(Dr and Dr

LEFT AXILLARY CONTENTS: The sections show a total of twenty nine lymph nodes, with the largest node (30mm) almost entirely replaced by metastasis (1/29). There are sheets of large atypical epithelioid and spindle shaped, heavily pigmented neoplastic cells within the lymph node with focal extra nodal extension. The features are consistent with metastatic melanoma. The remaining 28 lymph nodes show reactive changes, with some small nodes (Block A, B) containing pigment-laden macrophages within the sinuses.

SUMMARY

LEFT AXILLARY LYMPH NODE DISSECTION - METASTATIC MELANOMA, in one of twenty nine (1/29) lymph nodes

REPORTED BY: Dr

A Unit of:

Printed:

This

Page 1 of 1

Source: NCI Genomic Data Commons file e670c040-e323-46b3-98f2-aab4efc72bd2 (TCGA-EE-A29E.C3C1DB41-46B0-4162-BAEE-5FCFF18A696D.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).